CCDI case PBBPXX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/b6e80f59-74c6-48e4-8154-07e65e3403dc

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, biphasic: ICD-O-3 morphology code: 9043/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 13.7 years (5,006 days).

Biospecimens (3 samples)
- Sample 0DESUC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DESUD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DESUQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
